Somatic mutation profile of tumor specimen TCGA-OR-A5L6-01A (aliquot TCGA-OR-A5L6-01A-11D-A29I-10) from TCGA case TCGA-OR-A5L6, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 60.4 years (22,057 days).
Specimen TCGA-OR-A5L6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bec9d374-ba2f-44e2-bc30-df6c07c04f09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L6-10C (Blood Derived Normal), aliquot TCGA-OR-A5L6-10C-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/318e101a-4cb8-4900-bcc9-e1b6bf8c9252

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Frame Shift Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH8 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434590, CM042090, COSV101238303; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARFGEF2 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 90/180 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484627377; called by muse, mutect2, varscan2
- CYP26C1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs761068228, COSV99591634; called by muse, mutect2, varscan2
- F5 | c.3843C>A p.S1281R | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV63125572; called by muse, mutect2
- FBXL13 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs763482414; called by muse, mutect2
- IARS1 | c.3518A>G p.Y1173C | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.619); catalogued as rs560795216; called by muse, mutect2, varscan2
- JAK1 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV61098464; called by muse, mutect2, varscan2
- LAMA2 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as CM102051; called by muse, mutect2, varscan2
- MUC16 | c.24296C>G p.S8099C | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs542234427; called by muse, mutect2, varscan2
- NIFK | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs748810988; called by muse, mutect2, varscan2
- OR52E2 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV58611932; called by muse, mutect2, varscan2
- OR5D13 | c.706C>G p.R236G | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV62332785; called by muse, mutect2, varscan2
- PCDHB10 | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as rs781935975, COSV53378396; called by muse, mutect2, varscan2
- PID1 | c.416G>A p.R139Q (on ENST00000354069 / NM_001330156.1; = p.R137Q on NM_017933.5) | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs769912855, COSV62483513; called by muse, mutect2, varscan2
- PTPRD | c.2993C>A p.T998K | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV61981604; called by muse, mutect2, varscan2
- RFLNA | c.344C>T p.S115L (on ENST00000546355 / NM_001365156.1; = p.S34L on NM_181709.4) | Missense Mutation (SNP) | VAF 78/489 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58038430; called by muse, mutect2
- SI | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV52299407; called by muse, mutect2, varscan2
- TMEM176A | c.519G>T p.R173S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747977717; called by muse, mutect2, varscan2
- TMEM63C | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs756710566, COSV53604461; called by muse, mutect2, varscan2
- ADSS2 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CANX | c.1258A>G p.S420G | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by mutect2, varscan2
- CTCFL | c.1072A>G p.K358E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- EVI5L | c.749dup p.Q251Afs*44 | Frame Shift Ins (INS) | VAF 13/82 reads (16%) | called by mutect2, pindel, varscan2
- HMCN1 | c.8587G>A p.V2863I | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LYZL1 | c.573_574del p.C191* (on ENST00000375500; = p.C145* on NM_032517.6) | Frame Shift Del (DEL) | VAF 25/124 reads (20%) | called by pindel, varscan2
- NEB | c.16985A>T p.Q5662L | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PIGU | c.415_418del p.K139Wfs*7 | Frame Shift Del (DEL) | VAF 36/143 reads (25%) | called by mutect2, pindel, varscan2
- SIRT1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SOHLH2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBL3 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT1A5 | c.294A>T p.Q98H | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDC37L1 | c.399G>A p.K133= | Silent (SNP) | VAF 62/164 reads (38%) | called by muse, mutect2, varscan2
- GRM6 | c.510C>T p.P170= | Silent (SNP) | VAF 75/125 reads (60%) | called by muse, mutect2, varscan2
- INKA1 | c.630C>T p.D210= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as rs146996587; called by muse, mutect2, varscan2
- KRT75 | c.63G>A p.S21= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs775841339; called by muse, mutect2, varscan2
- MPI | c.483A>G p.L161= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs752681489; called by muse, mutect2, varscan2
- PACC1 | c.279T>A p.R93= | Silent (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- PTPRA | c.141C>G p.A47= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as rs775353797, COSV53783509; called by muse, mutect2, varscan2
- PTPRF | c.1338A>G p.G446= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- ANK2 | c.2900+5164G>T | Intron (SNP) | VAF 24/151 reads (16%) | catalogued as rs923208535; called by muse, mutect2, varscan2
